Somatic mutation profile of tumor specimen 0DX4FR from CCDI case PBCRBN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Choroid plexus papilloma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.8 years (656 days).
Specimen 0DX4FR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11aec498-bd41-4fcf-b0f3-34214d70bff5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX4EX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6169ba71-136d-469e-93bc-b2e741154547

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TG | c.3570T>G p.C1190W | Missense Mutation (SNP) | VAF 23/737 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55100183; called by muse, mutect2
- DIAPH3 | c.1826C>T p.P609L (on ENST00000400324 / NM_001042517.2; = p.P346L on NM_030932.3) | Missense Mutation (SNP) | VAF 109/481 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC12A8 | c.1109T>G p.V370G | Missense Mutation (SNP) | VAF 30/696 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- UNC80 | c.4751C>A p.T1584K | Missense Mutation (SNP) | VAF 72/1470 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); called by muse, mutect2
- CTBS | c.24C>T p.R8= | Silent (SNP) | VAF 32/774 reads (4%) | catalogued as rs1329158546; called by muse, mutect2
- LRRC7 | c.1421-34A>T | Intron (SNP) | VAF 32/327 reads (10%) | catalogued as rs1415560984; called by mutect2, varscan2
